Somatic mutation profile of tumor specimen TCGA-PE-A5DC-01A (aliquot TCGA-PE-A5DC-01A-12D-A27P-09) from TCGA case TCGA-PE-A5DC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.6 years (26,514 days).
Specimen TCGA-PE-A5DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0b8139b-5df2-4db8-bb8b-c0205a67a392.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PE-A5DC-10A (Blood Derived Normal), aliquot TCGA-PE-A5DC-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9bf9438-a5e6-4c22-8c93-c8173cf368d3

The open-access MAF lists 114 somatic variants for this specimen: 81 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 31, Frame Shift Del 8, Splice Site 5, In Frame Del 3, Splice Region 3, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD17B3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.351); catalogued as rs119481076, CM0910010, CM940951, COSV100931226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3260G>A p.R1087H (on ENST00000614293; = p.R1057H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1196123224, COSV99688107; called by muse, mutect2, varscan2
- ACOT9 | c.818C>G p.T273S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV100321365; called by muse, mutect2, varscan2
- ADAM19 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99977904; called by muse, mutect2, varscan2
- ADGRF5 | c.1036+1G>T p.X346_splice | Splice Site (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99346092; called by muse, mutect2, varscan2
- AGBL4 | c.1132G>C p.V378L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.079); catalogued as COSV100484488; called by muse, mutect2, varscan2
- ALDH1L2 | c.2718T>G p.G906= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99311204; called by muse, mutect2, varscan2
- ANKRD39 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100450504; called by muse, mutect2, varscan2
- ARFGAP1 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as rs757459121, COSV100796708; called by muse, mutect2, varscan2
- ARHGAP26 | c.1921T>G p.L641V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV99191240; called by muse, mutect2, varscan2
- ARHGAP6 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100273319, COSV57293443; called by muse, mutect2, varscan2
- BCAN | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100228308; called by muse, mutect2, varscan2
- CBLN4 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as rs138871300; called by muse, mutect2, varscan2
- CCDC144A | c.2813T>C p.L938P | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100138632; called by muse, mutect2, varscan2
- CCDC85A | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV101339506; called by muse, mutect2, varscan2
- CDH17 | c.1656G>C p.K552N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV99217755; called by muse, mutect2, varscan2
- CIZ1 | c.726del p.K242Nfs*21 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV99476890; called by mutect2, pindel, varscan2
- CNTNAP3 | c.3126C>G p.I1042M | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs1345354682, COSV99905301; called by muse, varscan2
- CNTNAP3 | c.3117A>T p.R1039S | Missense Mutation (SNP) | VAF 66/486 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99905305; called by muse, varscan2
- CPNE5 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs375106654; called by muse, mutect2, varscan2
- EHMT2 | c.1582A>T p.N528Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100977232; called by muse, mutect2, varscan2
- EMILIN3 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100182703; called by muse, mutect2, varscan2
- FAF2 | c.63+2T>G p.X21_splice | Splice Site (SNP) | VAF 31/68 reads (46%) | catalogued as COSV99990595; called by muse, mutect2, varscan2
- FAT1 | c.8247G>T p.E2749D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.039); catalogued as COSV71671691; called by muse, mutect2, varscan2
- FOXD3 | c.680A>G p.N227S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV100942916; called by muse, mutect2, varscan2
- GABRR3 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV101512328; called by muse, mutect2, varscan2
- GPR137B | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100858361, COSV63990843; called by muse, mutect2, varscan2
- GPR39 | c.1112A>T p.E371V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV100258146; called by muse, mutect2, varscan2
- KCNA1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838319; called by muse, mutect2, varscan2
- KCNH6 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100121166; called by muse, mutect2, varscan2
- LRRC43 | c.382T>G p.F128V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs760408826, COSV100336858; called by muse, mutect2, varscan2
- MAGEB18 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100305564, COSV57465046; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV99686067; called by muse, mutect2, varscan2
- MICU1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); catalogued as COSV100741860; called by muse, mutect2, varscan2
- NMBR | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs1385476873, COSV57803787; called by muse, mutect2, varscan2
- NRCAM | c.1932C>T p.Y644= | Splice Region (SNP) | VAF 7/14 reads (50%) | catalogued as rs775186263, COSV61033658, COSV61044677; called by mutect2, varscan2
- NUTM1 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100412444; called by muse, mutect2, varscan2
- OAT | c.989G>A p.C330Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100920463; called by muse, mutect2, varscan2
- OR2G6 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100598251, COSV100598347; called by muse, mutect2, varscan2
- OR4C13 | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs1555015851, COSV101634212; called by muse, mutect2, varscan2
- OTOF | c.3769G>C p.G1257R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as COSV55505061, COSV99718374; called by muse, mutect2, varscan2
- PON3 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV55700788, COSV99672604; called by muse, mutect2, varscan2
- PRAM1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs746078484, COSV99725753; called by muse, mutect2, varscan2
- PTPN23 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99650835; called by muse, mutect2, varscan2
- PYGM | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV99377394; called by muse, mutect2, varscan2
- RBMS3 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV99823115; called by muse, mutect2, varscan2
- RDH13 | c.760G>A p.G254R (on ENST00000415061 / NM_001145971.2; = p.G183R on NM_138412.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs752343665, COSV99401583; called by muse, mutect2, varscan2
- RREB1 | c.4868C>G p.A1623G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV100619608; called by muse, mutect2, varscan2
- SERPINA5 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.144); catalogued as COSV100291736; called by muse, mutect2, varscan2
- SLC4A2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.342); catalogued as rs1209119628, COSV100055631; called by muse, mutect2, varscan2
- SLC7A10 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); catalogued as COSV99472409; called by muse, mutect2
- SNAPIN | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as COSV100721979; called by muse, mutect2, varscan2
- SPHKAP | c.4833C>G p.I1611M (on ENST00000392056 / NM_001142644.2; = p.I1582M on NM_030623.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV100764290, COSV60874973; called by muse, mutect2
- SPON1 | c.1662C>T p.C554= | Splice Region (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100116366; called by muse, mutect2, varscan2
- STAB1 | c.3679-1G>T p.X1227_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100402003; called by muse, mutect2, varscan2
- TBC1D8 | c.2963T>C p.M988T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99961540; called by muse, mutect2, varscan2
- TIAM1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54548401; called by muse, mutect2
- TLK2 | c.93T>G p.N31K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100409425; called by muse, mutect2, varscan2
- TMEM132E | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100396612; called by muse, mutect2
- TMEM182 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101305404, COSV68424971; called by muse, mutect2, varscan2
- TNS2 | c.1052G>C p.C351S (on ENST00000314250 / NM_170754.4; = p.C361S on NM_015319.2) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100048496; called by muse, mutect2, varscan2
- TUBA1C | c.1021A>T p.I341F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV99988876; called by muse, mutect2, varscan2
- UBE3B | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV55096413; called by muse, mutect2, varscan2
- UGT1A1 | c.435T>G p.F145L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100530604; called by muse, mutect2, varscan2
- VPS8 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99803108; called by muse, mutect2, varscan2
- VRK2 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100418155; called by muse, mutect2, varscan2
- ZAN | c.4797C>G p.I1599M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100769988; called by muse, mutect2, varscan2
- ZNF74 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV100677522; called by muse, mutect2, varscan2
- ZNF91 | c.30+2T>G p.X10_splice | Splice Site (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100323231; called by muse, mutect2, varscan2
- CCDC146 | c.1582_1589del p.F528Lfs*11 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- CEP41 | c.208-33_208-2del p.X70_splice | Splice Site (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel
- CSNK2A1 | c.586_593delinsGT p.Y196_K198delinsV | In Frame Del (DEL) | VAF 7/34 reads (21%) | called by pindel, varscan2*
- CTDSPL2 | c.373_383del p.K125* | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- EHD3 | c.1583del p.P528Rfs*20 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- FAT2 | c.7690_7692del p.G2564del | In Frame Del (DEL) | VAF 15/43 reads (35%) | called by pindel, varscan2
- LHCGR | c.799_804del p.N267_L268del | In Frame Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- MARCHF11 | c.1152_1192del p.D385Sfs*9 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel
- NUAK1 | c.365_373del p.F122_K125delins* | Nonsense Mutation (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- SAPCD1 | c.10_37del p.Q4Rfs*58 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- SPOUT1 | c.815_819del p.A272Vfs*3 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- TTC30B | c.30_67del p.D11Qfs*20 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- ADGRV1 | c.15987C>T p.Y5329= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs142097643; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.7521C>T p.S2507= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100003039; called by muse, mutect2, varscan2
- BCAN | c.39C>A p.V13= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100228307; called by muse, mutect2, varscan2
- BICD1 | c.420G>A p.L140= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99862759; called by muse, mutect2
- CDH1 | c.1902G>A p.A634= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs754404223, COSV55726976; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSF1R | c.1174C>T p.L392= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99642573; called by muse, mutect2, varscan2
- CTTNBP2 | c.378C>T p.S126= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1279856418, COSV50404147, COSV99354454; called by muse, mutect2, varscan2
- DNAH10 | c.12423C>G p.L4141= (on ENST00000409039; = p.L4080= on NM_207437.3) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101292464; called by muse, mutect2, varscan2
- ECD | c.120G>A p.E40= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99654859; called by muse, mutect2, varscan2
- EPHA5 | c.1677C>A p.T559= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99900137; called by mutect2, varscan2
- FRS3 | c.1443G>A p.R481= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99442992; called by muse, mutect2
- GRM3 | c.2571T>C p.S857= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100862718; called by muse, mutect2, varscan2
- KIAA1755 | c.1644C>T p.S548= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99642402; called by muse, mutect2, varscan2
- LRRC73 | c.915A>T p.G305= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99447134; called by muse, mutect2, varscan2
- MAP1A | c.1080G>A p.E360= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs999794911, COSV100288984; called by muse, mutect2, varscan2
- MOB2 | c.372G>T p.V124= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100326628; called by muse, mutect2, varscan2
- MYO15A | c.10302C>T p.I3434= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99233729; called by muse, mutect2, varscan2
- NEB | c.7236T>C p.Y2412= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1301275168, COSV99425763; called by muse, mutect2, varscan2
- NMUR1 | c.555C>T p.V185= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1456360578, COSV100532053; called by muse, mutect2, varscan2
- NR1D1 | c.132G>T p.L44= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99225692; called by muse, mutect2, varscan2
- PDZD2 | c.6093T>G p.A2031= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99225977; called by muse, mutect2, varscan2
- PKHD1L1 | c.9156G>C p.G3052= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101006601; called by muse, mutect2, varscan2
- PRKG1 | c.1713A>G p.P571= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100907378; called by muse, mutect2, varscan2
- RPS4X | c.645C>A p.G215= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100289122; called by muse, mutect2, varscan2
- SBNO2 | c.387C>T p.L129= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100684826; called by muse, mutect2, varscan2
- SIX4 | c.591C>A p.A197= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV53670021, COSV99382401; called by muse, mutect2, varscan2
- SLC44A5 | c.1473A>G p.K491= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs748454522, COSV100902289; called by muse, mutect2, varscan2
- SPAG9 | c.1704G>A p.K568= (on ENST00000262013 / NM_001130528.3; = p.K554= on NM_003971.6) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100005602; called by muse, mutect2, varscan2
- TSHZ1 | c.2391C>T p.A797= (on ENST00000580243 / NM_001308210.2; = p.A752= on NM_005786.6) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100433843; called by muse, mutect2, varscan2
- ZFYVE19 | c.960C>T p.N320= (on ENST00000355341 / NM_001077268.2; = p.N310= on NM_032850.5) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100146369; called by muse, mutect2, varscan2
- ZNF462 | c.3162C>T p.P1054= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs770852721, COSV52945900; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4738G>T | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100447087, COSV61087713; called by muse, mutect2, varscan2
- RPS3 | c.31-286_31-281del | Intron (DEL) | VAF 30/145 reads (21%) | called by mutect2, pindel, varscan2
